Somatic mutation profile of tumor specimen TCGA-30-1718-01A (aliquot TCGA-30-1718-01A-01W-0633-09) from TCGA case TCGA-30-1718, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 44.9 years (16,400 days).
Specimen TCGA-30-1718-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) af321925-ea51-46ff-91fa-a48f553321a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-30-1718-10A (Blood Derived Normal), aliquot TCGA-30-1718-10A-01W-0633-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/85b23b90-4dd7-4739-9c79-ef78d2e7f553

The open-access MAF lists 161 somatic variants for this specimen: 119 protein-altering or splice-affecting, 40 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 40, Nonsense Mutation 7, Splice Site 4, Frame Shift Ins 2, 3'Flank 1, Splice Region 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 97/158 reads (61%) | hotspot (GDC flag); catalogued as rs1057520607, CM144128, COSV52689734, COSV52701760, COSV52773998, COSV53851434; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.917C>T p.T306I | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764244115, COSV52629082; called by muse, mutect2, varscan2
- AC004922.1 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs745516024, COSV53163565; called by muse, mutect2, varscan2
- ACSS3 | c.814G>T p.D272Y | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99699175; called by muse, mutect2, varscan2
- ADAM12 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs369702251; called by muse, mutect2, varscan2
- AHNAK2 | c.10145C>T p.P3382L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs763306348, COSV100318253; called by muse, mutect2
- AMD1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.335); catalogued as COSV100924506, COSV64387878; called by muse, mutect2
- ATG16L2 | c.942G>C p.Q314H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100352295; called by muse, mutect2
- ATRX | c.3449A>T p.Q1150L | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV100971159; called by muse, mutect2, varscan2
- CACNG7 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351971857, COSV99712146; called by muse, mutect2
- CCDC77 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.16); catalogued as COSV53473350; called by muse, mutect2, varscan2
- CCNB3 | c.3895A>G p.K1299E | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV52074608; called by muse, mutect2, varscan2
- CCR2 | c.1103T>C p.L368P | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV99432569; called by muse, mutect2, varscan2
- CDK8 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 16/334 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as rs1465189992, COSV101037411; called by muse, mutect2
- CHD1 | c.2334G>C p.E778D | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV52341111; called by mutect2, varscan2
- CKAP5 | c.592G>C p.A198P | Missense Mutation (SNP) | VAF 59/129 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV56368828; called by muse, mutect2, varscan2
- CLCN3 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as rs767730345, COSV61626717; called by muse, mutect2, varscan2
- CLTC | c.2901G>C p.R967S | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52247436, COSV52248473; called by muse, mutect2, varscan2
- CNTNAP5 | c.1207C>A p.L403M | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV101443616; called by muse, mutect2
- COL4A5 | c.3989G>C p.G1330A | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60363218, COSV60367809; called by muse, mutect2, varscan2
- CSMD2 | c.4558C>G p.L1520V | Missense Mutation (SNP) | VAF 49/144 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV53919631; called by muse, mutect2, varscan2
- CSMD3 | c.743C>A p.S248Y | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.837); catalogued as COSV52351468; called by muse, mutect2
- CWH43 | c.1185T>C p.L395= | Splice Region (SNP) | VAF 6/126 reads (5%) | catalogued as COSV99893714; called by muse, mutect2
- CYFIP1 | c.3173A>G p.H1058R | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.216); catalogued as COSV57410544; called by muse, mutect2, varscan2
- CYSLTR1 | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 34/108 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.607); catalogued as COSV64820338; called by muse, mutect2, varscan2
- DBF4 | c.1910A>G p.Y637C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV99719470; called by muse, mutect2
- DDI2 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 26/247 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.867); catalogued as COSV60779963; called by muse, mutect2, varscan2
- EEF1A1 | c.173G>A p.W58* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as COSV58549857; called by muse, mutect2, varscan2
- EFL1 | c.2792A>C p.Q931P | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV51606317; called by muse, mutect2, varscan2
- EIF4G3 | c.1498C>G p.Q500E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.185); catalogued as COSV99944995; called by muse, mutect2
- FARSA | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as COSV100108943; called by muse, mutect2
- FAT3 | c.8409G>T p.K2803N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs771160027, COSV53121139; called by muse, varscan2
- FGR | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.558); catalogued as COSV100925918, COSV64969570; called by muse, mutect2, varscan2
- FNTA | c.623G>C p.W208S | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100172607; called by muse, mutect2
- GIPC2 | c.241-1G>T p.X81_splice | Splice Site (SNP) | VAF 11/317 reads (3%) | catalogued as COSV100883293; called by muse, mutect2
- GPR15 | c.267G>C p.W89C | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52520674; called by muse, mutect2, varscan2
- GRM4 | c.538G>A p.A180T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65214328; called by muse, mutect2, varscan2
- GSPT2 | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV100468248; called by muse, mutect2
- GTF2B | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 14/96 reads (15%) | catalogued as rs763288295, COSV65137037; called by muse, mutect2, varscan2
- HSPA12B | c.605G>C p.R202P | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV54767267; called by muse, mutect2
- IDH3A | c.268A>T p.K90* | Nonsense Mutation (SNP) | VAF 11/69 reads (16%) | catalogued as COSV55113109; called by muse, mutect2, varscan2
- IRS4 | c.2526C>A p.D842E | Missense Mutation (SNP) | VAF 78/406 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV64534184; called by muse, varscan2
- ITK | c.760T>G p.L254V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV68435364; called by muse, mutect2, varscan2
- JCAD | c.345C>A p.Y115* | Nonsense Mutation (SNP) | VAF 12/266 reads (5%) | catalogued as COSV100948497; called by muse, mutect2
- KDM5A | c.4342C>T p.L1448F | Missense Mutation (SNP) | VAF 34/264 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777181874, COSV66993021; called by muse, mutect2, varscan2
- KIF4A | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 13/221 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100979590; called by muse, mutect2
- LARP1 | c.718_719insA p.R240Qfs*23 (on ENST00000518297 / NM_033551.3; = p.R163Qfs*23 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 30/131 reads (23%) | catalogued as COSV60427857; called by mutect2, pindel, varscan2
- LMOD3 | c.1604G>A p.R535K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs929921978, COSV101341982; called by muse, mutect2
- LRP1B | c.8402C>A p.P2801H | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV101258195; called by muse, mutect2
- MAGEC2 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV56002007, COSV99909618; called by muse, mutect2
- MAP3K14 | c.2049C>A p.H683Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV60923781; called by muse, mutect2, varscan2
- MDGA2 | c.1728G>C p.R576S (on ENST00000399232 / NM_001113498.2; = p.R278S on NM_182830.4) | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100637599; called by muse, mutect2, varscan2
- MED12L | c.4847A>G p.E1616G | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.188); catalogued as COSV56381557; called by muse, mutect2, varscan2
- MFAP3 | c.1052A>C p.N351T | Missense Mutation (SNP) | VAF 16/126 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1458262111, COSV59456477; called by muse, mutect2, varscan2
- MOV10 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV99588411; called by muse, mutect2
- MPDZ | c.376A>T p.I126F | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV59943950; called by muse, mutect2, varscan2
- MROH5 | c.2278A>G p.M760V | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1476366431, COSV71301766; called by muse, mutect2, varscan2
- MUSK | c.2116G>A p.A706T | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV51888156; called by muse, varscan2
- MVP | c.766A>G p.T256A | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV62422231; called by muse, mutect2, varscan2
- MYADM | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as rs940848866, COSV61239929; called by muse, mutect2, varscan2
- NCOA6 | c.2962C>A p.P988T | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.468); catalogued as COSV62864438, COSV62868209; called by muse, mutect2, varscan2
- NCR1 | c.356-1G>C p.X119_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | catalogued as COSV52556961, COSV99401051; called by muse, mutect2
- NPNT | c.881G>A p.W294* | Nonsense Mutation (SNP) | VAF 23/142 reads (16%) | catalogued as COSV59754387; called by muse, mutect2, varscan2
- NSD3 | c.982C>G p.R328G | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV100388487, COSV100388770; called by muse, mutect2
- OPCML | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.012); catalogued as COSV59420469; called by muse, mutect2
- OPN3 | c.881C>G p.S294W | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59364204, COSV59364701; called by muse, mutect2, varscan2
- OR10G8 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV70908646; called by muse, mutect2, varscan2
- OR2J2 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 22/728 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs986904037, COSV101013413; called by muse, mutect2
- PCDHB2 | c.1892T>G p.L631R | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV50579429; called by muse, mutect2, varscan2
- PDE1C | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.381); catalogued as COSV100373096; called by muse, mutect2, varscan2
- PHF20 | c.3015G>C p.Q1005H | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs751778845, COSV64976146; called by mutect2, varscan2
- PIGC | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 10/274 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as COSV99278293; called by muse, mutect2
- PLEKHG1 | c.1939G>C p.G647R | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV62048043, COSV62048546; called by muse, mutect2, varscan2
- PPP1R15B | c.1830G>C p.Q610H | Missense Mutation (SNP) | VAF 41/85 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.16); catalogued as COSV65815860; called by muse, mutect2, varscan2
- PRSS23 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 36/134 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753521872, COSV54707022; called by muse, mutect2, varscan2
- PSG8 | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 38/343 reads (11%) | SIFT tolerated (0.93); PolyPhen benign (0.012); catalogued as rs752870751, COSV60612498; called by muse, mutect2, varscan2
- PSME4 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1473982960, COSV66365548; called by muse, mutect2, varscan2
- QPRT | c.826G>T p.A276S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.387); catalogued as COSV99569026; called by muse, mutect2
- RAB20 | c.626G>T p.R209I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.074); catalogued as COSV57440855; called by muse, mutect2, varscan2
- RAB7A | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV99414187, COSV99414336; called by muse, mutect2
- SAMD12 | c.507A>C p.R169S | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV100126422; called by muse, mutect2
- SLC10A5 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101594262, COSV72828320; called by muse, mutect2
- SLC5A7 | c.1264C>A p.L422I | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.158); catalogued as COSV99886975; called by muse, mutect2
- SLC6A5 | c.1073A>G p.N358S | Missense Mutation (SNP) | VAF 43/227 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV54227719; called by muse, mutect2, varscan2
- SLC8A3 | c.1448G>C p.R483T | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63521960; called by muse, mutect2, varscan2
- SPATA31E1 | c.703G>A p.A235T | Missense Mutation (SNP) | VAF 47/197 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.452); catalogued as COSV57792404; called by muse, mutect2, varscan2
- SPIN4 | c.521G>T p.G174V | Missense Mutation (SNP) | VAF 13/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100633379; called by muse, mutect2
- SRRM2 | c.5456G>T p.G1819V | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV57074345, COSV57079675; called by muse, mutect2, varscan2
- STC1 | c.599A>G p.D200G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs756456558, COSV51688783; called by muse, mutect2, varscan2
- STT3B | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55503134; called by muse, mutect2, varscan2
- SYNE1 | c.11881C>G p.Q3961E | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as COSV55003006; called by muse, mutect2, varscan2
- TDRD1 | c.2770+1G>T p.X924_splice | Splice Site (SNP) | VAF 23/57 reads (40%) | catalogued as COSV52591610; called by muse, mutect2, varscan2
- TMPRSS11E | c.1079G>T p.G360V | Missense Mutation (SNP) | VAF 44/493 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100542451, COSV100542458; called by muse, mutect2
- TRMT5 | c.182C>A p.P61Q | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.133); catalogued as COSV99712235; called by muse, mutect2
- TTN | c.39284G>C p.C13095S (on ENST00000591111; = p.C5671S on NM_003319.4) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | PolyPhen benign (0.288); catalogued as COSV60112123; called by muse, mutect2, varscan2
- TTN | c.24595C>A p.L8199I (on ENST00000591111; = p.L7272I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | PolyPhen possibly damaging (0.699); catalogued as COSV60112169, COSV60179504; called by muse, mutect2, varscan2
- TULP1 | c.1470C>A p.N490K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57692834; called by muse, mutect2, varscan2
- UBXN6 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.498); catalogued as rs764291815, COSV56679046; called by muse, mutect2, varscan2
- UNC13A | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs560413297, COSV53194672; called by muse, mutect2
- UPB1 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV58114027; called by muse, mutect2, varscan2
- VSIG4 | c.143G>C p.G48A | Missense Mutation (SNP) | VAF 26/182 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.892); catalogued as COSV66073951; called by muse, varscan2
- WDR13 | c.988T>C p.S330P | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV54332107; called by muse, mutect2, varscan2
- WDR37 | c.703C>A p.P235T | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); catalogued as rs750430192, COSV54129327; called by muse, mutect2, varscan2
- WDR75 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 32/179 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs148423434; called by muse, mutect2, varscan2
- WSCD1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 52/84 reads (62%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.916); catalogued as COSV58495992; called by muse, varscan2
- XIAP | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 27/170 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as COSV63022600; called by muse, mutect2, varscan2
- YIPF1 | c.380G>A p.C127Y | Missense Mutation (SNP) | VAF 33/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1426974785, COSV99301049; called by muse, mutect2
- ZFHX4 | c.4301T>A p.F1434Y | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV99265195; called by muse, mutect2
- ZMAT2 | c.10G>C p.G4R | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.063); catalogued as rs1421492062, COSV51227097; called by muse, mutect2, varscan2
- ZNF2 | c.549G>T p.E183D (on ENST00000611147 / NM_001291605.2; = p.E170D on NM_021088.4) | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV99728587; called by muse, mutect2
- ZNF302 | c.1345G>T p.E449* (on ENST00000627982; = p.E370* on NM_018443.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV101416509; called by muse, mutect2
- ZNF521 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64125812, COSV64129437; called by muse, mutect2, varscan2
- ZNF804A | c.648T>G p.F216L | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56452053; called by muse, mutect2, varscan2
- ARHGEF9 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2
- CTTNBP2 | c.1402dup p.S468Kfs*13 | Frame Shift Ins (INS) | VAF 54/547 reads (10%) | called by mutect2, pindel, varscan2
- NPC1 | c.1326+1G>C p.X442_splice | Splice Site (SNP) | VAF 15/147 reads (10%) | called by mutect2, varscan2
- RINL | c.1541A>G p.D514G (on ENST00000591812 / NM_001195833.2; = p.D400G on NM_198445.4) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SMG1 | c.3567_3589del p.K1189Nfs*16 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, varscan2
- TMEM138 | c.335G>T p.W112L | Missense Mutation (SNP) | VAF 19/629 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2
- ADGRB3 | c.1419C>A p.G473= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as rs199826937, COSV65399717; called by muse, mutect2, varscan2
- AHNAK2 | c.10143G>T p.V3381= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs766985483, COSV100318254; called by muse, mutect2
- ATP12A | c.1035C>T p.A345= | Silent (SNP) | VAF 24/167 reads (14%) | catalogued as COSV54517690; called by muse, mutect2, varscan2
- CACNA1B | c.4743G>A p.Q1581= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV53129307; called by muse, mutect2, varscan2
- COG5 | c.1983T>A p.P661= (on ENST00000347053 / NM_001379512.1; = p.P682= on NM_006348.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV51753362; called by muse, mutect2, varscan2
- COL17A1 | c.3012G>A p.P1004= | Silent (SNP) | VAF 134/406 reads (33%) | catalogued as rs368653483, COSV62227161, COSV62229518; called by muse, mutect2, varscan2
- CSMD2 | c.6090G>A p.E2030= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as rs1434227288; called by muse, mutect2
- CSMD3 | c.744C>G p.S248= | Silent (SNP) | VAF 4/95 reads (4%) | called by muse, mutect2
- DDR1 | c.1833C>G p.R611= (on ENST00000324771; = p.R574= on NM_001954.4) | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV100241824; called by muse, mutect2
- DHRS2 | c.120G>C p.V40= | Silent (SNP) | VAF 17/75 reads (23%) | catalogued as COSV51632310; called by muse, mutect2, varscan2
- DNAJC5 | c.75C>T p.N25= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs189308547, COSV62671077; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- EPHA10 | c.1545C>T p.T515= | Silent (SNP) | VAF 71/389 reads (18%) | catalogued as rs769884416, COSV57624538; called by muse, mutect2, varscan2
- FOXM1 | c.2022A>G p.Q674= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV61206303; called by muse, mutect2, varscan2
- FRY | c.2568C>G p.L856= | Silent (SNP) | VAF 34/289 reads (12%) | catalogued as COSV66571646; called by muse, mutect2, varscan2
- GALK2 | c.957C>T p.N319= | Silent (SNP) | VAF 5/79 reads (6%) | catalogued as COSV100509043; called by muse, mutect2
- GJA8 | c.909G>A p.K303= | Silent (SNP) | VAF 16/108 reads (15%) | catalogued as COSV53789142; called by muse, mutect2, varscan2
- GPR174 | c.987A>C p.T329= | Silent (SNP) | VAF 18/129 reads (14%) | catalogued as COSV52132822; called by muse, mutect2, varscan2
- HTT | c.4923G>A p.L1641= | Silent (SNP) | VAF 39/352 reads (11%) | catalogued as COSV61863433; called by muse, mutect2, varscan2
- MAMLD1 | c.1947T>A p.S649= | Silent (SNP) | VAF 6/107 reads (6%) | called by muse, mutect2
- MED12 | c.3387T>A p.A1129= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100379012; called by muse, mutect2
- MSH6 | c.2073C>G p.L691= | Silent (SNP) | VAF 58/713 reads (8%) | catalogued as COSV99316457; called by muse, mutect2
- NRXN2 | c.2670G>A p.Q890= | Silent (SNP) | VAF 15/141 reads (11%) | catalogued as COSV55454925; called by muse, mutect2, varscan2
- OR2K2 | c.210C>A p.G70= (on ENST00000374428; = p.G41= on NM_205859.2) | Silent (SNP) | VAF 54/193 reads (28%) | catalogued as rs139925839; called by muse, mutect2, varscan2
- OR7G3 | c.828G>T p.V276= | Silent (SNP) | VAF 52/289 reads (18%) | catalogued as COSV59640463; called by muse, mutect2, varscan2
- OR8H3 | c.516C>T p.N172= | Silent (SNP) | VAF 49/298 reads (16%) | catalogued as COSV57909389; called by muse, mutect2, varscan2
- PCDHB8 | c.1752C>G p.G584= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1554281396, COSV50775170; called by muse, mutect2, varscan2
- PER1 | c.3567G>C p.R1189= | Silent (SNP) | VAF 30/71 reads (42%) | catalogued as COSV57920038; called by muse, mutect2, varscan2
- PLXDC1 | c.1464C>A p.G488= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100195603; called by muse, mutect2
- SBSN | c.324A>G p.A108= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV101510088; called by muse, mutect2
- SGSM1 | c.417C>G p.V139= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV101240928; called by muse, mutect2
- SIGLEC12 | c.585C>A p.A195= (on ENST00000291707 / NM_053003.4; = p.A77= on NM_033329.2) | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV52462131; called by muse, mutect2, varscan2
- SLC25A43 | c.1008T>C p.P336= | Silent (SNP) | VAF 52/273 reads (19%) | catalogued as COSV54218102; called by muse, mutect2, varscan2
- SLC35G6 | c.336C>T p.V112= | Silent (SNP) | VAF 32/276 reads (12%) | catalogued as COSV59492843; called by muse, mutect2, varscan2
- SPESP1 | c.195T>C p.Y65= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as COSV99534333; called by muse, mutect2, varscan2
- TEX264 | c.393G>A p.V131= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs751948757, COSV58134659; called by muse, varscan2
- TRMT112 | c.345C>T p.N115= | Silent (SNP) | VAF 16/214 reads (7%) | catalogued as COSV99134726; called by muse, mutect2
- WBP11 | c.900A>G p.E300= | Silent (SNP) | VAF 55/172 reads (32%) | catalogued as COSV53763197; called by muse, mutect2, varscan2
- WDR7 | c.3390T>A p.L1130= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV99589890; called by muse, mutect2
- ZFHX3 | c.1290C>G p.S430= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as COSV99213739; called by muse, mutect2, varscan2
- ZNF239 | c.81T>C p.I27= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as COSV60018927; called by muse, mutect2, varscan2
- CYB5R4 | c.412+993T>A | Intron (SNP) | VAF 9/35 reads (26%) | catalogued as COSV63746673; called by muse, mutect2, varscan2
- NOL9 | chr1:6519482 A>T | 3'Flank (SNP) | VAF 9/101 reads (9%) | catalogued as COSV100891491; called by muse, mutect2
